Somatic mutation profile of tumor specimen C3N-03182-02 (aliquot CPT0206560009) from CPTAC case C3N-03182, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.8 years (17,461 days).
Specimen C3N-03182-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c8fe595-2332-455b-9e34-6b758c6bcb45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03182-71 (Blood Derived Normal), aliquot CPT0206610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe4d4b00-faf4-4190-84f1-19fe0c5c4a64

The open-access MAF lists 244 somatic variants for this specimen: 146 protein-altering or splice-affecting, 62 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 62, Intron 12, 3'UTR 9, RNA 8, Frame Shift Del 6, Frame Shift Ins 5, Splice Region 4, Nonsense Mutation 3, 5'UTR 3, 5'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL1 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 163/284 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs1319018632; called by muse, mutect2, varscan2
- ADAR | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 198/334 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs759837017; called by muse, mutect2, varscan2
- ADCY1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 115/401 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs372552814; called by muse, mutect2, varscan2
- ADGRB1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 339/572 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs747421642, COSV60102340; called by muse, mutect2, varscan2
- ADGRE1 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs201690943; called by muse, mutect2, varscan2
- AMER2 | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 164/297 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs760756687; called by muse, mutect2, varscan2
- ANAPC5 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 202/302 reads (67%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99945964; called by muse, mutect2, varscan2
- AQP12B | c.352C>T p.R118C (on ENST00000621682; = p.R130C on NM_001102467.2) | Missense Mutation (SNP) | VAF 224/373 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs372967359; called by muse, mutect2, varscan2
- ARHGAP29 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs747589753; called by muse, mutect2, varscan2
- ASTE1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778902667, COSV53908393; called by muse, mutect2, varscan2
- BCORL1 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 225/293 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.706); catalogued as rs1444481019, COSV54403753; called by muse, mutect2, varscan2
- BRSK2 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs759518070, COSV57540676; called by muse, mutect2
- C10orf71 | c.4069G>A p.A1357T | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs1274873954, COSV60507204; called by muse, mutect2, varscan2
- C19orf81 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 360/553 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.199); catalogued as rs185628472; called by muse, mutect2, varscan2
- CABP5 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs763411623; called by muse, mutect2, varscan2
- CAP2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 310/548 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141863829, COSV57729659; called by muse, mutect2, varscan2
- CAVIN2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 129/226 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV58424034; called by muse, mutect2, varscan2
- CBARP | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 163/268 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99289989; called by muse, mutect2, varscan2
- CBLB | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 66/109 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV51438509; called by muse, mutect2, varscan2
- CCDC103 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 381/663 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs745767863; called by muse, mutect2, varscan2
- CCL5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 177/318 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs780510680; called by muse, mutect2, varscan2
- CDH16 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 215/352 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762526771; called by muse, mutect2, varscan2
- CEP131 | c.1612G>A p.E538K (on ENST00000269392 / NM_001319228.2; = p.E535K on NM_014984.4) | Missense Mutation (SNP) | VAF 184/286 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369438843; called by muse, mutect2, varscan2
- CES4A | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 187/314 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs529170797; called by muse, mutect2, varscan2
- CNIH1 | c.150+1G>A p.X50_splice | Splice Site (SNP) | VAF 25/46 reads (54%) | catalogued as rs1162861625; called by muse, mutect2, varscan2
- CROT | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as rs765930660, COSV58973915; called by muse, mutect2, varscan2
- CUEDC1 | c.958_961del p.F320Nfs*12 | Frame Shift Del (DEL) | VAF 211/383 reads (55%) | catalogued as rs776086737; called by mutect2, pindel, varscan2
- D2HGDH | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs199908032, CM101390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC1B | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 109/381 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs202011984, COSV54013109; called by muse, mutect2, varscan2
- DNAH6 | c.6656G>A p.R2219H | Missense Mutation (SNP) | VAF 239/402 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244674127; called by muse, mutect2, varscan2
- DPP10 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV59711718; called by muse, varscan2
- DPT | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 340/590 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs749307060; called by muse, mutect2, varscan2
- EPHA6 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 113/193 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.427); catalogued as rs368808214; called by muse, mutect2, varscan2
- ERBIN | c.1349G>A p.W450* | Nonsense Mutation (SNP) | VAF 51/93 reads (55%) | catalogued as rs1317188998; called by muse, mutect2, varscan2
- FAM181A | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 296/501 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs368140620, COSV50888168; called by muse, mutect2, varscan2
- FAM205A | c.3355C>T p.L1119F | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.367); catalogued as rs474408; called by muse, varscan2
- FGD2 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 135/213 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs746920455; called by muse, mutect2, varscan2
- FKRP | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 207/293 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768762059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXRED2 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 81/126 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as rs202049182, COSV99340854; called by muse, mutect2, varscan2
- FRK | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 133/206 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs377628003; called by muse, mutect2, varscan2
- GALR3 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 170/317 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1376777342, COSV50764186; called by muse, varscan2
- GIPC3 | c.883C>T p.R295C (on ENST00000644946; = p.F290= on NM_133261.3) | Missense Mutation (SNP) | VAF 296/514 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs764287192, COSV100461521, COSV59258619; called by muse, mutect2, varscan2
- GPR119 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 280/377 reads (74%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs140173805, COSV52275676; called by muse, mutect2, varscan2
- GRM7 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 96/153 reads (63%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs202073441, COSV63130656; called by muse, mutect2, varscan2
- HCFC1 | c.3652G>A p.V1218I | Missense Mutation (SNP) | VAF 204/263 reads (78%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1557114050; called by muse, mutect2, varscan2
- HDAC1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 82/179 reads (46%) | catalogued as rs771427696; called by pindel, varscan2
- HDAC9 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1161136341, COSV67784060, COSV67787392; called by muse, mutect2, varscan2
- HECW1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 219/792 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs770727253, COSV67836527; called by muse, mutect2, varscan2
- IFNL1 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 220/377 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs753364897, COSV61317801; called by muse, mutect2, varscan2
- IGFN1 | c.2245G>A p.A749T (on ENST00000295591 / NM_001367841.1; = p.A3206T on NM_001164586.2) | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.274); catalogued as rs761832601; called by muse, mutect2, varscan2
- IRX6 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 101/167 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139251893; called by muse, mutect2, varscan2
- ITGAM | c.1711C>T p.R571W (on ENST00000648685 / NM_001145808.2; = p.R570W on NM_000632.4) | Missense Mutation (SNP) | VAF 99/158 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs375394349; called by muse, mutect2, varscan2
- JPH2 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.184); catalogued as rs770986432, COSV65903804; called by muse, mutect2, varscan2
- KALRN | c.7219C>T p.R2407C (on ENST00000360013 / NM_001024660.4; = p.R710C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747606269, COSV52261167; called by muse, mutect2, varscan2
- KEL | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 184/661 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs760716472, COSV62334737; called by muse, mutect2, varscan2
- KIR2DL4 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 348/555 reads (63%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1464936898; called by muse, mutect2, varscan2
- KRT16 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 569/931 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs1209457883, COSV56967047; called by muse, mutect2, varscan2
- KRTAP9-3 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 503/819 reads (61%) | SIFT deleterious (0.03); catalogued as COSV68616480; called by muse, mutect2, varscan2
- L1CAM | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 148/190 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs201496144, COSV62826830; called by muse, mutect2, varscan2
- LIMA1 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57963999; called by muse, mutect2
- LRRC37A2 | c.3763G>A p.A1255T | Missense Mutation (SNP) | VAF 284/1015 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200419055; called by muse, mutect2, varscan2
- MAGI2 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 206/468 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs201984030; called by muse, mutect2, varscan2
- MC5R | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs953055132, COSV61255137; called by muse, varscan2
- MC5R | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 120/454 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1052690404; called by muse, varscan2
- MECR | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 178/284 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs143281690; called by muse, mutect2, varscan2
- MEX3C | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.813); catalogued as rs368857821; called by muse, mutect2, varscan2
- MFSD6L | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 258/461 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs776309544, COSV100266002; called by muse, mutect2, varscan2
- MROH7 | c.2964+8C>T | Splice Region (SNP) | VAF 416/618 reads (67%) | catalogued as rs748181225, COSV59871088; called by muse, mutect2, varscan2
- MSH2 | c.2240T>G p.I747R | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD004537; called by muse, mutect2, varscan2
- MUC16 | c.32528dup p.H10844Pfs*2 | Frame Shift Ins (INS) | VAF 80/118 reads (68%) | catalogued as rs745530053; called by mutect2, varscan2
- MUC5B | c.13703C>T p.T4568M | Missense Mutation (SNP) | VAF 290/643 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.662); catalogued as rs200570748; called by muse, mutect2, varscan2
- MYO3A | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs777926817, COSV99779776; called by muse, mutect2, varscan2
- MYOM2 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 233/372 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs140876932; called by muse, mutect2, varscan2
- NBEAL2 | c.5288G>A p.R1763H | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs374607617; called by muse, mutect2, varscan2
- NCOR2 | c.3178dup p.R1060Pfs*2 | Frame Shift Ins (INS) | VAF 48/82 reads (59%) | catalogued as rs749518211; called by mutect2, varscan2
- NOS1 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 90/145 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs754582579, COSV57620467; called by muse, mutect2, varscan2
- NRG1 | c.754G>A p.A252T (on ENST00000405005 / NM_013964.5; = p.A257T on NM_013956.5) | Missense Mutation (SNP) | VAF 267/462 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs771092162, COSV55152234, COSV99827524; called by muse, mutect2, varscan2
- OR2F2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs375593151; called by muse, mutect2, varscan2
- PATJ | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as rs200079447, COSV57157558; called by muse, mutect2, varscan2
- PCDHB15 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 394/644 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV50858094; called by muse, mutect2, varscan2
- PCDHB4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 144/219 reads (66%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs1425672587, COSV52024729; called by muse, mutect2, varscan2
- PCLO | c.11891G>A p.R3964Q | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs369285880, COSV100429081; called by muse, mutect2, varscan2
- PDX1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 85/141 reads (60%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs751645380; called by muse, mutect2, varscan2
- PIK3C2B | c.3563C>T p.T1188M | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1450496692; called by muse, mutect2, varscan2
- PLCG2 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1353126296, COSV100842699, COSV63869326; called by muse, mutect2, varscan2
- PLXNC1 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 87/158 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs371753668; called by muse, mutect2, varscan2
- PTGES2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 171/287 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1040048423; called by muse, mutect2, varscan2
- PXDN | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 239/376 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs377274038; called by muse, mutect2, varscan2
- RASGRF1 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 132/200 reads (66%) | SIFT tolerated (0.39); PolyPhen benign (0.312); catalogued as rs755638460, COSV67249952; called by muse, mutect2, varscan2
- RNF103 | c.1102_1105del p.I368Ffs*15 | Frame Shift Del (DEL) | VAF 60/100 reads (60%) | catalogued as rs779542435; called by pindel, varscan2
- RPUSD1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 231/405 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1028518519; called by muse, mutect2, varscan2
- SLC4A7 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs372621060; called by muse, mutect2, varscan2
- SLC8A3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.972); catalogued as rs373370870; called by muse, mutect2, varscan2
- SMARCAL1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 189/295 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480919035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMTN | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 231/386 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs1218758055; called by muse, mutect2, varscan2
- SOHLH1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 412/649 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs138784478; called by muse, mutect2, varscan2
- SOX14 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 30/649 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148822399; called by muse, mutect2
- STRBP | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as COSV62119768; called by muse, mutect2, varscan2
- STX3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376160845; called by muse, mutect2, varscan2
- TKTL2 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 164/289 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138835887, COSV54918334; called by muse, mutect2, varscan2
- TM2D1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs377583831; called by muse, mutect2, varscan2
- TMEM52B | c.524C>T p.S175L (on ENST00000381923 / NM_001079815.1; = p.S155L on NM_153022.4) | Missense Mutation (SNP) | VAF 181/295 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as rs748030036, COSV53727927; called by muse, mutect2, varscan2
- TNFRSF8 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 298/506 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746581720; called by muse, mutect2, varscan2
- TP53 | c.569dup p.P191Sfs*18 | Frame Shift Ins (INS) | VAF 368/728 reads (51%) | catalogued as COSV52939661; called by mutect2, pindel, varscan2
- TPST2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); catalogued as rs1186220430, COSV58682194; called by muse, mutect2, varscan2
- TRAPPC5 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 209/352 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58039702; called by muse, mutect2, varscan2
- TRIB3 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs779380315, COSV53931475; called by muse, varscan2
- TRIM58 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565939415, COSV63570326; called by muse, mutect2, varscan2
- TRMT44 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 385/576 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs532797174, COSV101077682, COSV67664150; called by muse, mutect2, varscan2
- TSC1 | c.210G>A p.K70= | Splice Region (SNP) | VAF 245/429 reads (57%) | catalogued as rs1060503219, COSV100051894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSLP | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 182/261 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746539761; called by muse, mutect2, varscan2
- UMODL1 | c.2483G>T p.G828V (on ENST00000408910 / NM_001004416.2; = p.G956V on NM_173568.3) | Missense Mutation (SNP) | VAF 165/259 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV68570579; called by muse, mutect2, varscan2
- VIL1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 104/165 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs1344522901, COSV50288101; called by muse, mutect2, varscan2
- WDFY3 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1444096931, COSV99882788; called by muse, mutect2, varscan2
- WNT3A | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 174/253 reads (69%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs572229142; called by muse, mutect2, varscan2
- ZNF217 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 231/770 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV56594609; called by muse, mutect2, varscan2
- ZSCAN10 | c.1063G>A p.G355S (on ENST00000252463; = p.G410S on NM_032805.3) | Missense Mutation (SNP) | VAF 191/310 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs576668601; called by muse, mutect2, varscan2
- ALDH16A1 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 215/382 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C19orf47 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 273/480 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCND2 | c.222_224del p.E75del | In Frame Del (DEL) | VAF 56/114 reads (49%) | called by pindel, varscan2
- CDKN2C | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 232/380 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD1 | c.1547C>T p.T516M | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ERRFI1 | c.855dup p.R286Qfs*7 | Frame Shift Ins (INS) | VAF 130/264 reads (49%) | called by mutect2, pindel, varscan2
- EZHIP | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 340/446 reads (76%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FEZ1 | c.1093_1096del p.N365Ffs*5 | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | called by mutect2, pindel, varscan2
- GPAT2 | c.2311C>T p.H771Y | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2C | c.10734T>A p.H3578Q | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMB3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 443/690 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- LRRC72 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 180/674 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOM2 | c.4001+2_4001+5del p.X1334_splice | Splice Site (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- NICN1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOP16 | c.393+5G>A | Splice Region (SNP) | VAF 208/335 reads (62%) | called by muse, mutect2, varscan2
- OR9Q1 | c.528del p.F176Lfs*10 | Frame Shift Del (DEL) | VAF 45/140 reads (32%) | called by mutect2, pindel, varscan2
- PARD6B | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.738); called by muse, varscan2
- PGGHG | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 202/545 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI1 | c.5686_5690del p.S1896Efs*6 | Frame Shift Del (DEL) | VAF 182/327 reads (56%) | called by mutect2, pindel, varscan2
- RB1 | c.2037del p.I680Sfs*16 | Frame Shift Del (DEL) | VAF 168/342 reads (49%) | called by mutect2, pindel, varscan2
- RBM19 | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 170/254 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS22 | c.3367A>T p.I1123F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- RRAGD | c.1162A>G p.K388E | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- STC1 | c.565A>T p.N189Y | Missense Mutation (SNP) | VAF 332/533 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- STIP1 | c.672+13del | Splice Region (DEL) | VAF 63/149 reads (42%) | called by mutect2, pindel, varscan2
- SYCP1 | c.2642dup p.R882Efs*6 | Frame Shift Ins (INS) | VAF 19/37 reads (51%) | called by mutect2, varscan2
- TTN | c.41624A>G p.N13875S (on ENST00000591111; = p.N6451S on NM_003319.4) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.1164G>C p.Q388H | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ZNF711 | c.878T>A p.M293K | Missense Mutation (SNP) | VAF 162/200 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ABCA12 | c.1005G>A p.T335= (on ENST00000272895 / NM_173076.3; = p.T17= on NM_015657.3) | Silent (SNP) | VAF 86/151 reads (57%) | catalogued as rs750852160; called by muse, mutect2, varscan2
- ACTG1 | c.9A>G p.E3= | Silent (SNP) | VAF 38/1050 reads (4%) | catalogued as rs375069806; called by muse, mutect2
- AHRR | c.765G>A p.P255= | Silent (SNP) | VAF 426/713 reads (60%) | catalogued as rs371473301; called by muse, mutect2, varscan2
- AL592490.1 | c.777C>T p.D259= | Silent (SNP) | VAF 150/231 reads (65%) | catalogued as COSV69425780; called by muse, mutect2, varscan2
- ASB18 | c.774G>A p.A258= | Silent (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- BEX1 | c.180G>T p.L60= | Silent (SNP) | VAF 179/242 reads (74%) | called by muse, mutect2, varscan2
- BTBD7 | c.3261C>T p.S1087= | Silent (SNP) | VAF 220/386 reads (57%) | catalogued as rs763885374; called by mutect2, varscan2
- CAMKK1 | c.1257G>A p.S419= | Silent (SNP) | VAF 311/554 reads (56%) | catalogued as rs759266418; called by muse, mutect2, varscan2
- CDH5 | c.1761C>T p.C587= | Silent (SNP) | VAF 708/1092 reads (65%) | catalogued as rs142148614; called by muse, mutect2, varscan2
- CDHR2 | c.3012G>A p.P1004= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs770353749; called by muse, mutect2, varscan2
- CDR2L | c.1071C>T p.D357= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs1303689177; called by muse, mutect2, varscan2
- CHST3 | c.885C>T p.R295= | Silent (SNP) | VAF 117/252 reads (46%) | catalogued as rs373546394; called by muse, mutect2, varscan2
- COA7 | c.339C>T p.N113= | Silent (SNP) | VAF 279/450 reads (62%) | catalogued as rs769532582; called by muse, mutect2, varscan2
- COL6A6 | c.4281A>G p.R1427= | Silent (SNP) | VAF 132/193 reads (68%) | called by muse, mutect2, varscan2
- CSPG4 | c.3444C>T p.A1148= | Silent (SNP) | VAF 149/243 reads (61%) | catalogued as rs753265519; called by muse, mutect2, varscan2
- CTTNBP2 | c.1101C>T p.G367= | Silent (SNP) | VAF 26/472 reads (6%) | catalogued as rs769627088, COSV50397453; called by muse, mutect2
- DNAH3 | c.5253C>T p.I1751= | Silent (SNP) | VAF 14/442 reads (3%) | called by muse, mutect2
- DOCK1 | c.5460G>A p.L1820= | Silent (SNP) | VAF 101/231 reads (44%) | called by muse, mutect2, varscan2
- EPC1 | c.219T>C p.V73= | Silent (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- HIVEP3 | c.1287C>T p.T429= | Silent (SNP) | VAF 92/150 reads (61%) | catalogued as rs371060064; called by muse, mutect2, varscan2
- IFNA2 | c.210C>T p.F70= | Silent (SNP) | VAF 116/199 reads (58%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.102C>T p.G34= | Silent (SNP) | VAF 267/457 reads (58%) | catalogued as rs1343694485; called by muse, mutect2, varscan2
- ITCH | c.126C>T p.Y42= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs757719312; called by muse, varscan2
- ITPR1 | c.8130G>A p.T2710= (on ENST00000354582; = p.T2655= on NM_002222.7) | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as rs368813104; called by muse, mutect2, varscan2
- JSRP1 | c.993C>T p.D331= | Silent (SNP) | VAF 49/69 reads (71%) | catalogued as rs905427761; called by muse, mutect2, varscan2
- KBTBD13 | c.471C>T p.Y157= | Silent (SNP) | VAF 57/78 reads (73%) | catalogued as rs550724858; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- KIF21A | c.4710A>G p.L1570= (on ENST00000361418 / NM_001378440.1; = p.L1557= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/95 reads (57%) | called by muse, mutect2, varscan2
- KMT2B | c.6594G>A p.G2198= | Silent (SNP) | VAF 91/150 reads (61%) | catalogued as rs779980966; called by muse, mutect2, varscan2
- LRRC37A3 | c.4401G>A p.S1467= | Silent (SNP) | VAF 425/768 reads (55%) | catalogued as rs369882842; called by muse, mutect2, varscan2
- LSR | c.159C>T p.A53= | Silent (SNP) | VAF 349/518 reads (67%) | catalogued as rs1347880943; called by muse, mutect2, varscan2
- MAD1L1 | c.1557G>A p.K519= | Silent (SNP) | VAF 158/642 reads (25%) | catalogued as COSV56247773; called by muse, mutect2, varscan2
- MROH9 | c.2484C>T p.F828= | Silent (SNP) | VAF 62/105 reads (59%) | catalogued as COSV100883413; called by muse, mutect2, varscan2
- MUC2 | c.360G>A p.P120= | Silent (SNP) | VAF 112/251 reads (45%) | catalogued as rs757973733; called by muse, mutect2, varscan2
- MYH11 | c.690C>T p.N230= | Silent (SNP) | VAF 190/352 reads (54%) | catalogued as rs561105158; ClinVar: likely benign; called by muse, mutect2, varscan2
- NID2 | c.1524C>T p.F508= | Silent (SNP) | VAF 193/330 reads (58%) | catalogued as rs1189350345; called by muse, mutect2, varscan2
- NPTN | c.687C>T p.N229= | Silent (SNP) | VAF 144/256 reads (56%) | called by muse, mutect2, varscan2
- OASL | c.1503C>A p.I501= | Silent (SNP) | VAF 85/131 reads (65%) | catalogued as rs143558393; called by muse, mutect2, varscan2
- P2RX2 | c.1089C>T p.S363= | Silent (SNP) | VAF 42/57 reads (74%) | catalogued as rs138785836, COSV100268119; called by muse, mutect2, varscan2
- PCDHGB7 | c.2241G>A p.T747= | Silent (SNP) | VAF 138/207 reads (67%) | called by muse, mutect2, varscan2
- PCSK5 | c.3741C>T p.C1247= | Silent (SNP) | VAF 143/224 reads (64%) | catalogued as rs768396393; called by muse, mutect2, varscan2
- PIEZO1 | c.351C>T p.N117= | Silent (SNP) | VAF 141/222 reads (64%) | catalogued as rs757593385; called by muse, mutect2, varscan2
- PPARGC1B | c.1662G>A p.G554= | Silent (SNP) | VAF 77/120 reads (64%) | catalogued as rs764661412; called by muse, mutect2, varscan2
- PRKCZ | c.96C>T p.D32= | Silent (SNP) | VAF 164/261 reads (63%) | catalogued as rs765678066; called by muse, mutect2, varscan2
- RAB37 | c.108G>A p.T36= | Silent (SNP) | VAF 158/282 reads (56%) | catalogued as rs770442943; called by muse, mutect2, varscan2
- RREB1 | c.4281C>T p.G1427= | Silent (SNP) | VAF 259/430 reads (60%) | catalogued as rs1375445835; called by muse, mutect2, varscan2
- RTL9 | c.1164G>A p.P388= | Silent (SNP) | VAF 146/177 reads (82%) | catalogued as rs374873915, COSV71825809, COSV71826276; called by muse, mutect2, varscan2
- SAMD15 | c.1308C>T p.N436= | Silent (SNP) | VAF 54/90 reads (60%) | catalogued as rs766848681, COSV99375300; called by muse, mutect2, varscan2
- SENP5 | c.1716C>T p.D572= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as rs369005871; called by muse, mutect2, varscan2
- SH3PXD2B | c.1623G>A p.R541= | Silent (SNP) | VAF 142/204 reads (70%) | called by muse, mutect2, varscan2
- SLC17A9 | c.1095G>A p.P365= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as rs756409472, COSV64848272; called by muse, mutect2, varscan2
- SLC18A3 | c.885C>T p.A295= | Silent (SNP) | VAF 137/292 reads (47%) | catalogued as rs1175704238, COSV60319945; called by muse, mutect2, varscan2
- SLURP2 | c.30C>T p.A10= | Silent (SNP) | VAF 218/370 reads (59%) | catalogued as rs755582944; called by muse, mutect2, varscan2
- SMAD2 | c.6G>A p.S2= | Silent (SNP) | VAF 260/669 reads (39%) | catalogued as rs1244575923, COSV50993416; called by muse, mutect2, varscan2
- SMAD7 | c.1167G>A p.P389= | Silent (SNP) | VAF 252/669 reads (38%) | catalogued as rs775414890; called by muse, mutect2, varscan2
- STK31 | c.429T>C p.Y143= | Silent (SNP) | VAF 58/150 reads (39%) | called by muse, mutect2, varscan2
- TCF3 | c.645C>T p.Y215= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs759295960; called by muse, mutect2, varscan2
- TGM6 | c.333C>T p.R111= | Silent (SNP) | VAF 263/975 reads (27%) | catalogued as rs1391702008; called by muse, mutect2, varscan2
- TVP23B | c.219G>A p.S73= | Silent (SNP) | VAF 99/174 reads (57%) | catalogued as rs753835939; called by muse, mutect2, varscan2
- UNC5A | c.1707C>T p.Y569= | Silent (SNP) | VAF 306/545 reads (56%) | catalogued as rs565155075; called by muse, mutect2, varscan2
- UNC93A | c.1224C>T p.H408= | Silent (SNP) | VAF 188/332 reads (57%) | catalogued as rs140401270, COSV57811031; called by muse, varscan2
- ZNF213 | c.585C>T p.V195= | Silent (SNP) | VAF 386/645 reads (60%) | catalogued as rs755016301; called by muse, mutect2, varscan2
- ZNF865 | c.2955G>A p.P985= | Silent (SNP) | VAF 147/237 reads (62%) | catalogued as rs1249884204; called by muse, mutect2, varscan2
- AC004890.2 | n.2119C>A | RNA (SNP) | VAF 30/646 reads (5%) | called by muse, mutect2
- AC090517.4 | c.-87dup | 5'UTR (INS) | VAF 12/37 reads (32%) | catalogued as rs767724108; called by mutect2, varscan2
- ADAMTS10 | c.1901-17G>A | Intron (SNP) | VAF 213/372 reads (57%) | catalogued as rs377649158; called by muse, mutect2, varscan2
- ADM2 | c.*52G>A | 3'UTR (SNP) | VAF 224/354 reads (63%) | catalogued as rs769729265; called by muse, mutect2, varscan2
- AGAP12P | n.2039G>A | RNA (SNP) | VAF 90/516 reads (17%) | catalogued as rs782540026; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848866 G>A | 5'Flank (SNP) | VAF 65/88 reads (74%) | called by muse, mutect2, varscan2
- AL590867.2 | n.259C>T | RNA (SNP) | VAF 268/480 reads (56%) | catalogued as rs572391759; called by muse, mutect2, varscan2
- CCDC33 | chr15:74336364 G>A | 3'Flank (SNP) | VAF 128/199 reads (64%) | catalogued as rs545733144; called by muse, mutect2, varscan2
- CNTNAP4 | c.86-23C>T | Intron (SNP) | VAF 168/306 reads (55%) | catalogued as rs781464979, COSV100268821; called by muse, mutect2, varscan2
- CYP2B7P | n.247G>A | RNA (SNP) | VAF 303/567 reads (53%) | catalogued as rs762034653; called by muse, mutect2, varscan2
- EPB41L1 | c.1669-1893G>A | Intron (SNP) | VAF 105/373 reads (28%) | catalogued as rs547771752; called by muse, mutect2, varscan2
- FA2H | c.*18G>A | 3'UTR (SNP) | VAF 98/156 reads (63%) | catalogued as rs780394370, COSV54726949; called by muse, mutect2, varscan2
- LILRB5 | c.1357+31C>T | Intron (SNP) | VAF 85/133 reads (64%) | catalogued as rs769642003; called by muse, mutect2, varscan2
- LINC00905 | n.529G>A | RNA (SNP) | VAF 55/97 reads (57%) | catalogued as rs550359142; called by muse, mutect2
- LINC01605 | n.607C>A | RNA (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- LRPPRC | c.3365-46A>G | Intron (SNP) | VAF 118/168 reads (70%) | called by muse, mutect2, varscan2
- LSP1 | c.*3G>A | 3'UTR (SNP) | VAF 60/135 reads (44%) | catalogued as rs371796282; called by muse, mutect2, varscan2
- MBD3L4 | c.-5C>T | 5'UTR (SNP) | VAF 32/106 reads (30%) | catalogued as rs1429000354; called by mutect2, varscan2
- MIR527 | n.76C>T | RNA (SNP) | VAF 45/74 reads (61%) | catalogued as rs762251060; called by muse, mutect2, varscan2
- MMEL1 | c.*29C>T | 3'UTR (SNP) | VAF 53/91 reads (58%) | catalogued as rs533809102; called by muse, mutect2, varscan2
- MPRIP | c.2163+4503C>T | Intron (SNP) | VAF 150/253 reads (59%) | catalogued as rs759982231, COSV57930329; called by muse, mutect2, varscan2
- NRIP1 | c.-537-7264G>A | Intron (SNP) | VAF 229/376 reads (61%) | called by muse, mutect2, varscan2
- POLR1H | chr6:30057098 C>T | 5'Flank (SNP) | VAF 48/92 reads (52%) | catalogued as rs1045221347; called by muse, mutect2, varscan2
- PTPN18 | c.1014-11C>G | Intron (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- RPS6KB2 | c.458-203T>C | Intron (SNP) | VAF 93/191 reads (49%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.132C>T | RNA (SNP) | VAF 161/270 reads (60%) | catalogued as rs552155737; called by muse, mutect2, varscan2
- SPATA1 | c.-48del | 5'UTR (DEL) | VAF 6/44 reads (14%) | catalogued as rs1045281118; called by mutect2, pindel
- TACC2 | c.33+11092G>A | Intron (SNP) | VAF 87/221 reads (39%) | catalogued as rs1458435301; called by muse, mutect2, varscan2
- TAFA4 | c.*1C>T | 3'UTR (SNP) | VAF 64/117 reads (55%) | catalogued as rs767390441, COSV55144757; called by muse, mutect2, varscan2
- TAZ | c.238+49G>T | Intron (SNP) | VAF 98/130 reads (75%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2128A>T | 3'UTR (SNP) | VAF 16/24 reads (67%) | catalogued as rs1036295833; called by muse, mutect2, varscan2
- TMEM70 | c.*19G>A | 3'UTR (SNP) | VAF 68/123 reads (55%) | catalogued as rs371128694; called by muse, mutect2
- TRHDE | chr12:72271911 G>A | 5'Flank (SNP) | VAF 188/285 reads (66%) | catalogued as rs1383989553; called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3196C>T | Intron (SNP) | VAF 14/23 reads (61%) | catalogued as rs760139685; called by muse, mutect2, varscan2
- VAPB | c.*1644C>T | 3'UTR (SNP) | VAF 131/413 reads (32%) | catalogued as rs935084987; called by muse, mutect2, varscan2
- ZNF44 | c.*208_*209del | 3'UTR (DEL) | VAF 11/28 reads (39%) | catalogued as rs1443154327; called by pindel, varscan2
